Surgical pathology report (de-identified scan), TCGA case TCGA-4Z-AA7W, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-4Z-AA7W-01A (Primary Tumor).

Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Bladder

- 1 - "Left Ureter."
- Absence of neoplasia.
- 2 - "Right Ureter."
- Absence of neoplasia
- 3 - "Bladder + prostate ".
- Bladder:
- Urothelial high grade carcinoma.
- Size: 3.0 x 2.0 x 1.5 cm
- Invasion reaching the muscular layer of the bladder.
- Angiolymphatic and perineural invasions: not detected.
- Prostate presenting miofibroepithelial hyperplasia.
- Surgical margins uninvolved by neoplasia.
- 4 - "Left lymphadenectomy."
- Presence of 10 lymph nodes uninvolved by neoplasia (0/10).
- 5 - "Right lymphadenectomy."
- Presence of 6 lymph nodes uninvolved by neoplasia (0/6).

Topography: bladder, NOS

Morphology: transitional cell carcinoma, NOS

Staging: pT2b pN0

CXLF ICD-O-3
Carcinoma, urothelial NOS 8120/3
path
Carcinoma, transitional cell NOS 8120/3
CXLF
Site: *Bladder, lateral wall* C67.2
path
Bladder NOS C67.9
W 3/18/14

Correct date confirmed 11/24/14

Source: NCI Genomic Data Commons file f169536a-1898-452b-b670-98cf763da022 (TCGA-4Z-AA7W.07E6E6FB-7E6B-4439-937A-9D479EFC7515.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).